Surgical pathology report (de-identified scan), TCGA case TCGA-QK-A6VB, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Emory University - Winship Cancer Inst., specimen TCGA-QK-A6VB-01A (Primary Tumor).

[page 1 of 5]
Document Type: Anat Path Reports
Document Date: UUID:7E1286FD-CACE-4FAB-8C22-9151DCE4DA3F
Document Status: TCGA-QK-A6VB-01A-PR Redacted
Document Title:
Performed By:
Verified By:
Encounter info:

IAD-03
Carcinoma, squamous cell
NOS 8070/3
Site Floor of mouth NOS
C04.9
JW 8/2/13

*** Final Report ***

Patient Name: Acc #:
MRN: DOB:
Location: Gender: M Collected:
Client: Received:
Submitting Phys: Reported:
Copy To Phys:

Final Surgical Pathology Report

Final Pathologic Diagnosis

- A. FLOOR OF MOUTH, LEFT, WIDE LOCAL EXCISION/PARTIAL GLOSSECTOMY/LEVEL I NECK DISSECTION, A1FS:**
- INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED (2.2 X 2.0 X 1.0CM).
- CARCINOMA INVOLVES SKELETAL MUSCLE BUNDLES.
- ALL MUCOSAL (INCLUDES PART B, C, D) AND SOFT TISSUE MARGINS NEGATIVE FOR CARCINOMA.
- NECK CONTENTS, LEFT LEVEL I:
- THREE LYMPH NODES NEGATIVE FOR CARCINOMA (0/3).
- SALIVARY GLAND WITH MINIMAL HISTOPATHOLOGIC CHANGE.
- SEE SYNOPTIC REPORT.
- B. ANTERIOR MARGIN, EXCISION, B1FS:**
- SQUAMOUS MUCOSA AND SKELETAL MUSCLE BUNDLES.
- NEGATIVE FOR HIGH GRADE DYSPLASIA AND INVASIVE CARCINOMA.
- C. MEDIAL MARGIN, EXCISION, C1FS:**
- SQUAMOUS MUCOSA AND REACTIVE LYMPHOID AGGREGATES.
- NEGATIVE FOR HIGH GRADE DYSPLASIA AND INVASIVE CARCINOMA.
- D. SUPERIOR MARGIN, EXCISION, D1FS:**
- SQUAMOUS MUCOSA AND SKELETAL MUSCLE BUNDLES.
- NEGATIVE FOR HIGH GRADE DYSPLASIA AND INVASIVE CARCINOMA.
- E. LYMPH NODES, LEFT LEVEL IA, NECK DISSECTION:**
- FOUR LYMPH NODES NEGATIVE FOR CARCINOMA (0/4).
- F. LYMPH NODES, LEFT LEVEL II, NECK DISSECTION/DISSECTION:**
- FIVE LYMPH NODES NEGATIVE FOR CARCINOMA (0/5).
- SEE COMMENT.
- G. LYMPH NODES, LEFT LEVEL III, NECK DISSECTION:**
- EIGHTEEN LYMPH NODES NEGATIVE FOR CARCINOMA (0/18).

[page 2 of 5]
**H. LYMPH NODES, LEFT LEVEL IV, NECK DISSECTION:
- TEN LYMPH NODES NEGATIVE FOR CARCINOMA (0/10).**

Comment

Part F: Recent PET imaging demonstrates a hypermetabolic left, Level II lymph node (1.4 x 1.2cm), however metastatic disease is not detected in any of the microscopic sections examined. Deeper levels into the tissue block of the largest Level II lymph node will be examined and reported as an addendum.

Electronically Signed by

Assisted by:

Synoptic Worksheet

A. Left posterior floor of mouth:

Clinical History:	No neoadjuvant therapy
Specimen:	Floor of mouth, NOS Other: Partial glossectomy, left
Received:	Fresh
Procedure:	Resection Neck (lymph node) dissection: Left: Levels I-IV
Specimen Integrity:	Intact
Specimen Size:	Greatest dimension: 10.5 cm Additional dimension: 5.0 cm Additional dimension: 4.5 cm
Specimen Laterality:	Left
Tumor Site:	Floor of mouth, NOS
Tumor Focality:	Single focus
Tumor Size:	Greatest dimension: 2.2 cm Additional dimension: 2.0 cm Additional dimension: 1.0 cm
Tumor Description:	Endophytic Ulcerated
Histologic Type:	Squamous cell carcinoma, conventional
Histologic Grade:	G2: Moderately differentiated
Margins:	Margins uninvolved by invasive carcinoma Distance from closest margin: 0.8 Unit of measurement: mm Margin(s): posterior
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Lymph Nodes, Extranodal Extension:	Not identified
Pathologic Staging (pTNM):	
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT4a: Moderately advanced local disease. Lip: Tumor invades through cortical bone, inferior alveolar nerve, floor of mouth, or skin of face, ie, chin or nose. Oral cavity: Tumor invades adjacent structures only
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis Number of regional lymph nodes examined: 40 Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Other: Tumor necrosis

[page 3 of 5]
Clinical History

Floor of mouth cancer. Floor mouth resection, mandibulectomy, glossectomy, neck dissection, tracheostomy and reconstruction with radial forearm free tissue, skin graft.

Specimen(s) Received

A: Left posterior floor of mouth
B: Anterior margin
C: Medial margin
D: Superior margin
E: Level 1A, Left Neck
F: Level 2, Left Neck
G: Level 3, Left Neck
H: Level 4, Left Neck

Gross Description

Specimen A is received fresh for intraoperative consultation labeled with the patient's name, medical record number and entitled "left posterior floor of mouth." The specimen consists of 4.5 x 4.0 x 3.5 cm portion of mucosa, a 3.5 x 2.0 x 0.3 cm submandibular gland, and soft tissue within an adjacent attached portion of salivary tissue and adipose tissue that measure 6.0 x 5.0 x 4.5 cm. In the mucosal part of the specimen there is a 2.2 x 2.0 x 1.0 cm lesion that is white with surrounding ulceration in the mucosa. This lesion appears to abut the lateral posterior edge, is 0.3 cm away from the anterior medial edge and 0.2 cm away from the anterior edge, 2.0 cm away from the inferior edge and superior edge. The specimen is inked as follows: anterior black, anterior medial orange, lingual gland yellow, posterior portion blue. Tumor does not involve lateral periosteum. The attached (in continuity with main specimen) soft tissue portion of the specimen per surgeon is the level I neck dissection. A portion of the tumor was tumor banked. The posterior mucosa portion of the specimen was en face, 1.7 x 1.1 x 0.5cm, and submitted for intraoperative consultation with the remaining tissue being submitted in cassette "A1FS." Gross photos are taken and are saved in Cassette summary is as follows.

Specimen B is received fresh for intraoperative consultation labeled with the patient's name, medical record number and entitled "anterior margin." The specimen consists of a portion of mucosal lined soft tissue that measure 1.5 x 1.0 x 0.5 cm. The specimen is submitted entirely for frozen section evaluation with the remaining tissue being submitted in cassette "B1FS." (Dictated by

Specimen C is received fresh for intraoperative consultation labeled with the patient's name, medical record number and entitled "medial margin." The specimen consists of two fragments of mucosal lined tissue with one fragment measuring 3.0 cm in length by 0.5 cm in width with a depth of 0.3 cm and the other fragment measuring 2.5 cm in length with a width of 0.6 cm and a depth of 0.3 cm. Fragment are submitted en face entirely for frozen section evaluation with the remaining tissue being submitted in cassette "C1FS." (Dictated by

Specimen D is received fresh for intraoperative consultation labeled with the patient's name, medical record number and entitled "superior margin." The specimen consists of a firm irregular soft tissue measuring 6.6 x 0.6 x 0.3 cm. The specimen is submitted entirely for frozen section analysis with the remaining tissue being submitted in cassette "D1FS." (Dictated by

Specimen E is received in formalin labeled with the patient's name, medical record number and entitled "level 1A, left neck." It consists of a piece of soft tissue that measure 5.0 x 4.0 x 1.0 cm. Inside the fibroadipose soft tissue multiple lymph nodes are identified. Cassette summary is as follows.

Specimen F is received in formalin labeled with the patient's name, medical record number and entitled "level 2, left neck." It consists of a single fragment of soft tissue that measure 7.0 x 5.0 x 1.5 cm. Inside the fibroadipose tissue multiple lymph nodes are identified. Cassette summary is as follows. (Dictated by

Specimen G is received in formalin labeled with the patient's name, medical record number and entitled "level 3, left neck." It consists of fibroadipose tissue that measure 6.0 x 4.0 x 3.0 cm. Multiple lymph nodes are identified. Cassette summary is as follows. (Dictated by

Specimen H is received fresh labeled with the patient's name, medical record number and entitled "level 4, left neck." It consists of a single piece of fibroadipose tissue that measure 4.5 x 4.0 x 1.0 cm. Multiple lymph nodes are identified. Cassette summary is as follows. (Dictated by

[page 4 of 5]
CASSETTE SUMMARY:

A1FS: Posterior soft tissue margin, en face
A2: Anterior medial mucosal edge (sent as anterior margin, B1FS)
A3: Anterior medial inferior mucosal edge (sent as medial margin, C1FS)
A4: Medial inferior mucosal edge (sent as medial margin, C1FS)
A5: Inferior to superior mucosal edge (sent as superior mucosal margin, D1FS)
A6: Posterior Inferior to lateral mucosal edge
A7: Posterior lateral to anterior medial mucosal edge
A8: Anterior soft tissue, shaved
A9: Anterior medial tissue, shaved
A10: Posterior medial soft tissue, shaved
A11: Lateral soft tissue, shaved
A12: Inferior soft tissue, shaved
A13: Perpendicular to the anterior medial edge
A14: Perpendicular to the anterior edge
A15: Perpendicular to the posterior edge (sent as posterior margin, A1FS)
A16: Perpendicular to the lateral posterior
A17: Representative section of mass
A18: Representative section of salivary gland
A19: Representative section of lingual gland
A20: Four potential lymph nodes
A21: Single lymph node, bivalved
A22: Four possible lymph nodes, submitted for lymph node evaluation
E1: Three possible lymph nodes
E2: Three possible lymph nodes
E3: Two possible lymph nodes
E4: One possible lymph node and fat for lymph node evaluation
E5,6: Fat sent for lymph node evaluation
F1: Single lymph node, 2.5 cm in greatest dimension, bisected
F2: Single lymph node, bisected
F3: Single lymph node, bisected
F4: Single lymph node, bisected
F5: Three whole lymph nodes
F6: Adipose tissue submitted for lymph node evaluation
G1: Single lymph node, bisected
G2: Four possible lymph nodes
G3: Four possible lymph nodes
G4: Four possible lymph nodes
G5: Three possible lymph nodes
G6: Four possible lymph nodes
H1: Three possible lymph nodes, submitted whole
H2: Five possible lymph nodes, submitted whole
H3: Three possible lymph nodes, submitted whole
H4-6: Adipose tissue, submitted for lymph node evaluation

Intraoperative Consult Diagnosis

A1FS: LEFT POSTERIOR FLOOR OF MOUTH, (FROZEN SECTION): NEGATIVE FOR CARCINOMA.

Frozen section results were communicated to the surgical team and were repeated back by
at and the specimen was received at

B1FS: ANTERIOR MARGIN (FROZEN SECTION): NEGATIVE FOR CARCINOMA AND HIGH GRADE DYSPLASIA.

C1FS: MEDIAL MARGIN, (FROZEN SECTION): NEGATIVE FOR CARCINOMA AND HIGH GRADE DYSPLASIA.

D1FS: SUPERIOR MARGIN, (FROZEN SECTION): NEGATIVE FOR CARCINOMA AND HIGH GRADE DYSPLASIA.

[page 5 of 5]
Frozen section results were communicated to the surgical team and were repeated back by
at In at

Pathologist:

Microscopic Description

Microscopic examination performed.

diPFA Discrepancy		/
Prob. Malignancy History		/
Dupl./Synchronous Primary		/
Noted		

Source: NCI Genomic Data Commons file a0d40252-26ad-4bb8-976b-7fffef01c8ad (TCGA-QK-A6VB.7E12B6FD-CACE-4FAB-8C22-9151DCE4DA3F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).